Gene-level copy-number profile of tumor specimen TCGA-IR-A3LH-01A from TCGA case TCGA-IR-A3LH, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIA1; Tumor grade: G4; Age at diagnosis: 49.6 years (18,118 days).
Specimen TCGA-IR-A3LH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.db86d02e-bdf5-42a6-b6dc-20825d86b3af.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IR-A3LH-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 356 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9944051e-8572-4dc6-9d0e-87918fa6621e

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 522; copy number 1: 7; copy number 2: 12,222; copy number 3: 7,829; copy number 4: 29,317; copy number 5: 7,932; copy number 6: 1,039; copy number 7: 1,013; copy number 8: 318; copy number 13: 9; copy number 19: 7; copy number 23: 52.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-IR-A3LH-01A-21D-A20T-01): tumor purity 0.49, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:37,534,940–37,551,536, 1 gene (within-gene range 0–2): LINC00547.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 68 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:112,990,447–113,184,377, 7 genes, copy number 19 (within-gene range 7–19): AC074044.1, GTPBP8, NEPRO, AC078785.1, AC078785.3, AC078785.2, LINC02044.
- chr11:97,657,464–103,092,194, 61 genes, copy number 13–23 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 7. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
